TCGA case TCGA-DX-A3LT — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7a72f7e-77b1-4d95-8f37-39a6cffc35dc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (3)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C49.1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,837 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 20.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 12.5; Tumor length measurement: 23; Tumor width measurement: 15.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 64.1 years (23,405 days); Days to diagnosis: 568 days (1.6 years); Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Upper limb, NOS. Age at diagnosis: 66.1 years (24,140 days); Days to diagnosis: 1,303 days (3.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (6 entries)
- Day 568 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 568 days (1.6 years).
- Days to follow up: 702 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 967 days (2.6 years); Disease response: Tumor Free.
- Day 1,303 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Upper limb, NOS; Days to recurrence: 1,303 days (3.6 years).
- Days to follow up: 1,331 days (3.6 years); Disease response: With Tumor.
- Days to follow up: 1,492 days (4.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3LT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-DX-A3LT-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3LT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3LT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Upper Extremity - Upper arm/elbow.
- Primary pathology: Margin status: Negative; Disease multifocal indicator: No; Well diff liposarc prior diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 103; Days from index date to radiation therapy ended: 147; Radiation therapy type: External; Radiation total dose: 6000; Radiation adjuvant units: cGy; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,492 days; disease-specific survival: no event (censored), 1,492 days; disease-free interval: event (new tumor event after initially disease-free), 568 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 568 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3LT-01A-12D-A21P-01): tumor purity 0.77, ploidy 1.79, whole-genome doublings 0.
